Somatic mutation profile of tumor specimen C3L-05848-01 (aliquot CPT0288750009) from CPTAC case C3L-05848, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 70.6 years (25,797 days).
Specimen C3L-05848-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f38284e-d893-45ea-b43b-f55a308270ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05848-31 (Blood Derived Normal), aliquot CPT0297030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c738e52-1ff4-4ae5-a522-1ed663d58d20

The open-access MAF lists 239 somatic variants for this specimen: 169 protein-altering or splice-affecting, 43 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 43, Nonsense Mutation 15, Intron 11, 5'UTR 6, Splice Site 5, 3'UTR 3, 5'Flank 3, RNA 3, Frame Shift Del 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICD2 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797045412; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 23/143 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 88/307 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL4 | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100876068; called by muse, mutect2
- AHNAK | c.13749G>A p.M4583I | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV57212843; called by muse, mutect2
- AHNAK | c.13315G>A p.E4439K | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV99946249; called by muse, mutect2
- ANKRD17 | c.5951C>G p.S1984C | Missense Mutation (SNP) | VAF 61/556 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.237); catalogued as rs909600274; called by muse, mutect2, varscan2
- ASCC1 | c.515T>C p.V172A (on ENST00000342444 / NM_001369085.1; = p.V144A on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs565723980; called by muse, mutect2, varscan2
- ATR | c.5545G>A p.E1849K | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV63384492, COSV63387168; called by muse, mutect2
- BCL7C | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772286392; called by muse, mutect2, varscan2
- BSN | c.8854G>A p.E2952K | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99606935; called by muse, mutect2
- CACNA1A | c.2953G>C p.E985Q | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV64203582; called by muse, mutect2, varscan2
- CACNA1C | c.6242G>C p.R2081T (on ENST00000399634 / NM_001167625.1; = p.R2010T on NM_000719.7) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.037); catalogued as COSV59704658, COSV59711382; called by muse, mutect2, varscan2
- CARF | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs375568309; called by muse, mutect2, varscan2
- CCDC60 | c.1023G>C p.Q341H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as COSV59549312; called by muse, mutect2
- CD1A | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV56861763; called by muse, mutect2
- CDHR3 | c.1975T>C p.S659P | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58415289; called by muse, mutect2
- CEP104 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as rs750473230, COSV65519184; called by muse, varscan2
- CEP63 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59676394; called by muse, mutect2
- CX3CL1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs781169716; called by muse, mutect2, varscan2
- DALRD3 | c.1576G>A p.E526K (on ENST00000341949 / NM_001009996.3; = p.E359K on NM_018114.5) | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV58244895; called by muse, mutect2, varscan2
- DCTN1 | c.2656T>C p.Y886H | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100720942; called by muse, mutect2
- DEFB125 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV101217601; called by muse, varscan2
- DHX34 | c.2767G>T p.D923Y | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100169450, COSV60895174; called by muse, mutect2, varscan2
- EHBP1L1 | c.4378C>G p.Q1460E | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100442408; called by muse, mutect2, varscan2
- FANCM | c.1923C>A p.F641L | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV57503612; called by muse, mutect2
- FAT2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV55820387; called by muse, mutect2, varscan2
- FBXL7 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 62/514 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs751600458, COSV61641776; called by muse, mutect2, varscan2
- GNAQ | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV54109441, COSV54115536; called by muse, mutect2, varscan2
- GRIA1 | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 18/210 reads (9%) | catalogued as COSV53587052, COSV53618249; called by muse, mutect2
- HAND2 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs200277716, COSV100854247, COSV64017962; called by muse, mutect2, varscan2
- HAVCR2 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs767274710; called by muse, mutect2, varscan2
- HCN2 | c.2648C>G p.S883W | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as rs1287730190; called by muse, mutect2, varscan2
- HCN4 | c.3323C>T p.S1108F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1234312215; called by muse, mutect2
- IWS1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.068); catalogued as COSV54866936; called by muse, mutect2
- KCNS1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1419017652; called by muse, mutect2
- KIFC2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 96/457 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.081); catalogued as rs543944085; called by muse, varscan2
- KL | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.463); catalogued as COSV66309559, COSV66309662; called by muse, mutect2
- LAMA4 | c.4799G>A p.G1600E (on ENST00000230538 / NM_001105206.3; = p.G1593E on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1554325184, COSV57903291; called by muse, mutect2
- MAP3K5 | c.2048G>C p.R683T | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV62892459; called by muse, mutect2, varscan2
- MELTF | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs749992290; called by muse, mutect2
- MSC | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1439093112; called by muse, mutect2, varscan2
- NOS3 | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99872079; called by muse, mutect2, varscan2
- PCNT | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.143); catalogued as COSV100854925; called by muse, mutect2, varscan2
- PDE5A | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs752046787, COSV99308976; called by muse, mutect2, varscan2
- PHLDB2 | c.1381A>G p.T461A | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs1378360447; called by muse, mutect2
- PIGT | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs750010387; called by muse, mutect2, varscan2
- PLAG1 | c.620A>G p.H207R | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100388266; called by muse, mutect2, varscan2
- PLBD2 | c.918C>G p.I306M | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55108420, COSV55109191; called by muse, mutect2
- PLCB2 | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 36/161 reads (22%) | catalogued as rs1253636768; called by muse, mutect2, varscan2
- PLXNC1 | c.1874C>G p.S625C | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as rs762710688, COSV51570565; called by muse, mutect2, varscan2
- PTPRD | c.3414-1G>C p.X1138_splice | Splice Site (SNP) | VAF 15/122 reads (12%) | catalogued as COSV61963781; called by muse, mutect2, varscan2
- RAD52 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352571686, COSV57273475; called by muse, mutect2
- RET | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs1564490056, CM129973, COSV60693275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC12A5 | c.2551G>A p.V851I (on ENST00000454036 / NM_001134771.2; = p.V828I on NM_020708.5) | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.682); catalogued as rs745380226; called by muse, mutect2, varscan2
- SLC6A17 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1169034207, COSV58992223, COSV58995777; called by muse, mutect2, varscan2
- SLITRK5 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as rs1216454901; called by muse, mutect2
- SNX21 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 12/177 reads (7%) | catalogued as COSV54169863; called by muse, mutect2
- SOX17 | c.192del p.E65Sfs*8 | Frame Shift Del (DEL) | VAF 72/394 reads (18%) | catalogued as COSV99810375; called by mutect2, pindel, varscan2
- TFE3 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs868987083, COSV100252983; called by muse, mutect2
- TLR7 | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV66124081, COSV66124225; called by muse, mutect2, varscan2
- TRIP10 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs570609735, COSV57571650; called by muse, mutect2, varscan2
- TTC39A | c.1510G>A p.E504K (on ENST00000447632 / NM_001297665.1; = p.E469K on NM_001080494.3) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV99397291; called by muse, mutect2, varscan2
- TULP1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as rs141173128, COSV57692042; called by mutect2, varscan2
- VWCE | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV57111877; called by muse, mutect2
- ZC3H12B | c.1920G>C p.Q640H | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs749055478; called by muse, mutect2, varscan2
- ZNF107 | c.2114C>G p.S705* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | catalogued as COSV61331322; called by muse, mutect2
- ZNF221 | c.433C>G p.Q145E | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52108611; called by muse, mutect2
- ZNF442 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.186); catalogued as rs1271954876; called by muse, mutect2, varscan2
- ZNF536 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 58/2420 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62817809; called by muse, mutect2
- ZNF646 | c.2893C>T p.Q965* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as COSV54922581; called by muse, mutect2, varscan2
- ADGRL3 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- ADGRV1 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- ADGRV1 | c.3344A>G p.D1115G | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); called by muse, mutect2
- AHI1 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- AHNAK | c.15918G>C p.L5306F | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALG13 | c.2396G>T p.R799L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ALG2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AMPD1 | c.2327T>G p.L776R | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ANKRD50 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGAP31 | c.4319G>T p.G1440V | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ARHGEF17 | c.5977C>G p.P1993A | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ARID4B | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ATP13A4 | c.2460C>G p.I820M | Missense Mutation (SNP) | VAF 19/411 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- C1QTNF6 | c.680G>C p.S227T | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALD1 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.417); called by muse, mutect2
- CAMKK2 | c.801C>G p.F267L | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CARD10 | c.2557G>C p.E853Q | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.115); called by muse, mutect2
- CCDC168 | c.16078G>A p.E5360K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CCDC168 | c.6412G>A p.E2138K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); called by mutect2, varscan2
- CD1B | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CEP104 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 69/201 reads (34%) | called by muse, mutect2, varscan2
- CHST8 | c.539A>C p.H180P | Missense Mutation (SNP) | VAF 19/533 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.658); called by muse, mutect2
- COL12A1 | c.3363C>G p.F1121L | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.438); called by muse, mutect2
- CRAT | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- CRB1 | c.3926G>C p.G1309A | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CSF1R | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CST6 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DHRS4L2 | c.505del p.S169Pfs*2 | Frame Shift Del (DEL) | VAF 22/158 reads (14%) | called by mutect2, varscan2
- DST | c.18004G>A p.E6002K (on ENST00000361203 / NM_001374722.1; = p.E3699K on NM_015548.5) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- EED | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- EFHC2 | c.1112-1G>A p.X371_splice | Splice Site (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- ELP1 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EML5 | c.4065G>C p.K1355N (on ENST00000380664; = p.K1363N on NM_183387.3) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2
- FAM151A | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXW7 | c.2072G>A p.G691E (on ENST00000281708 / NM_001349798.2; = p.G611E on NM_018315.5) | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FRAS1 | c.9457C>G p.L3153V | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- FRAS1 | c.11793G>C p.Q3931H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- GRM3 | c.2062C>A p.Q688K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXA13 | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2
- KIFC2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- LAMA2 | c.6925G>A p.D2309N | Missense Mutation (SNP) | VAF 27/357 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2
- LARP4 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- LRP1B | c.10741G>T p.G3581W | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRK1 | c.3057G>C p.K1019N | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2
- MAP1B | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MAP4K2 | c.1160C>G p.S387* | Nonsense Mutation (SNP) | VAF 26/262 reads (10%) | called by muse, mutect2
- MRPL9 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MRPS28 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2
- MTHFD1 | c.2840T>C p.L947P | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MTHFD1L | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- MYLK | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- NBR1 | c.2025G>A p.Q675= | Splice Region (SNP) | VAF 12/81 reads (15%) | called by muse, varscan2
- NKAP | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- NSUN2 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2
- OR52E8 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); called by muse, mutect2
- PBRM1 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PIGW | c.741G>C p.L247F | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PIK3C2G | c.2345C>T p.A782V (on ENST00000676171; = p.A741V on NM_004570.5) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRR32 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- PRSS35 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- RBM6 | c.1759T>A p.L587M | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RCC1L | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.579); called by muse, mutect2
- RELA | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2
- RGS9 | c.708G>C p.L236F | Missense Mutation (SNP) | VAF 40/574 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- RNF113B | c.728A>G p.H243R | Missense Mutation (SNP) | VAF 92/408 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RNF126 | c.880T>A p.S294T | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2
- RPS6KB1 | c.978+2T>C p.X326_splice | Splice Site (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- SALL2 | c.2363C>T p.S788L | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SART3 | c.1625C>G p.T542S (on ENST00000228284; = p.T524S on NM_014706.4) | Missense Mutation (SNP) | VAF 81/365 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SHOC2 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- SHPRH | c.1337T>G p.I446R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SKIDA1 | c.2004G>T p.E668D | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2
- SLC22A15 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC38A2 | c.874-1G>A p.X292_splice | Splice Site (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- SLF2 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- SLIT1 | c.3957C>G p.I1319M | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPAG17 | c.1095T>G p.Y365* | Nonsense Mutation (SNP) | VAF 23/225 reads (10%) | called by muse, mutect2
- SYNE1 | c.13714G>C p.D4572H (on ENST00000367255 / NM_182961.4; = p.D4501H on NM_033071.3) | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TDRD6 | c.5590G>C p.E1864Q | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TOP2B | c.2338C>T p.H780Y (on ENST00000264331 / NM_001330700.2; = p.H775Y on NM_001068.3) | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TPGS1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2
- TRAV4 | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- TRIM64C | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRPC5 | c.635C>G p.S212* | Nonsense Mutation (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- TSPAN17 | c.757-1G>C p.X253_splice | Splice Site (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- TTN | c.34987C>G p.L11663V (on ENST00000591111; = p.L10736V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | PolyPhen benign (0); called by muse, mutect2
- UNC13C | c.1924C>G p.H642D | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2
- WNK3 | c.4328C>T p.S1443L | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIRP1 | c.3267C>G p.I1089M | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZBED9 | c.2764G>C p.E922Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.479); called by muse, mutect2
- ZBTB33 | c.1902G>C p.Q634H | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.41); called by muse, mutect2
- ZFP91 | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- ZNF221 | c.730C>G p.H244D | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF221 | c.1799C>G p.S600* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ZNF518A | c.3746dup p.T1250Dfs*15 | Frame Shift Ins (INS) | VAF 17/95 reads (18%) | called by mutect2, pindel, varscan2
- ZNF569 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF615 | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF652 | c.841T>C p.F281L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ABCG4 | c.1818C>T p.L606= | Silent (SNP) | VAF 53/339 reads (16%) | catalogued as rs1456113217; called by muse, mutect2, varscan2
- AC008676.3 | c.382T>C p.L128= | Silent (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- AHNAK | c.8931G>T p.V2977= | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as COSV99949223; called by muse, mutect2, varscan2
- AQP11 | c.201G>A p.L67= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.3261C>T p.L1087= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs754642809; called by muse, mutect2, varscan2
- AXL | c.378C>T p.F126= | Silent (SNP) | VAF 21/313 reads (7%) | catalogued as rs540192002; called by muse, mutect2
- BLM | c.3738C>T p.L1246= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs1192075146; called by muse, mutect2, varscan2
- BRINP3 | c.2262A>G p.P754= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV66542020; called by muse, mutect2, varscan2
- C2orf78 | c.1749A>G p.K583= | Silent (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- CADPS2 | c.3744G>A p.Q1248= | Silent (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- CAPZB | c.672C>T p.I224= | Silent (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.5121G>A p.P1707= | Silent (SNP) | VAF 41/144 reads (28%) | catalogued as rs748889605, COSV62572655; called by muse, mutect2, varscan2
- CEP131 | c.1062G>A p.A354= | Silent (SNP) | VAF 27/293 reads (9%) | catalogued as rs867688843, COSV99488450; called by muse, mutect2
- DCAF8L1 | c.1248C>T p.L416= | Silent (SNP) | VAF 8/125 reads (6%) | catalogued as COSV71595303; called by muse, mutect2
- DOCK9 | c.3102C>T p.T1034= (on ENST00000376460 / NM_001366676.2; = p.T1035= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/235 reads (5%) | catalogued as rs1463326500; called by muse, mutect2
- GIT1 | c.1767C>T p.R589= | Silent (SNP) | VAF 46/238 reads (19%) | catalogued as rs866501754; called by muse, mutect2, varscan2
- GNB2 | c.378C>G p.L126= | Silent (SNP) | VAF 33/145 reads (23%) | called by muse, mutect2, varscan2
- GRM3 | c.1482C>G p.V494= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- HLF | c.783G>A p.E261= | Silent (SNP) | VAF 34/295 reads (12%) | catalogued as COSV56829804, COSV56832368; called by muse, mutect2, varscan2
- HLTF | c.2313G>C p.V771= | Silent (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2
- IL4 | c.237C>T p.F79= | Silent (SNP) | VAF 26/231 reads (11%) | called by muse, mutect2, varscan2
- ITGA4 | c.1014A>G p.R338= | Silent (SNP) | VAF 45/209 reads (22%) | called by muse, mutect2, varscan2
- MED29 | c.63G>A p.K21= | Silent (SNP) | VAF 26/636 reads (4%) | catalogued as COSV55394149, COSV99655552; called by muse, mutect2
- MYH7 | c.4275C>A p.I1425= | Silent (SNP) | VAF 49/381 reads (13%) | catalogued as rs57680382; ClinVar: likely benign; called by muse, mutect2, varscan2
- NGEF | c.912G>A p.R304= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- PLCE1 | c.258T>C p.S86= | Silent (SNP) | VAF 119/448 reads (27%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.265C>T p.L89= | Silent (SNP) | VAF 83/304 reads (27%) | called by muse, mutect2, varscan2
- PTPRT | c.12C>G p.L4= | Silent (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.862C>A p.R288= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV99910822; called by muse, mutect2, varscan2
- RGS3 | c.2769G>A p.Q923= (on ENST00000350696 / NM_001282923.2; = p.Q642= on NM_130795.4) | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as COSV100637173; called by muse, mutect2
- RIMBP3 | c.1329C>T p.L443= | Silent (SNP) | VAF 197/481 reads (41%) | catalogued as rs1452887794; called by muse, mutect2, varscan2
- RPS6KC1 | c.1770C>A p.L590= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV65302664; called by muse, mutect2
- SCN3A | c.5880G>C p.G1960= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2
- SGCE | c.600C>T p.F200= (on ENST00000647096; = p.F164= on NM_003919.3) | Silent (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- SLC8A3 | c.1461C>G p.V487= | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- SLX4IP | c.960G>A p.P320= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs142206094; called by muse, mutect2, varscan2
- SSR2 | c.171G>C p.V57= | Silent (SNP) | VAF 45/257 reads (18%) | catalogued as COSV55304265; called by muse, mutect2, varscan2
- STIL | c.3255G>A p.S1085= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as rs1450296852, COSV99681036; called by muse, mutect2, varscan2
- TCTE3 | c.6G>A p.E2= | Silent (SNP) | VAF 47/161 reads (29%) | called by muse, mutect2, varscan2
- TMED1 | c.102C>T p.F34= | Silent (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- TRPC3 | c.1506G>T p.V502= (on ENST00000379645 / NM_001366479.2; = p.V429= on NM_003305.2) | Silent (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- UBQLN3 | c.1914C>G p.L638= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- ZCCHC3 | c.147G>A p.E49= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs1172704632; called by muse, mutect2, varscan2
- AC092656.1 | n.205G>C | RNA (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- C10orf67 | c.206+588C>T | Intron (SNP) | VAF 17/137 reads (12%) | catalogued as rs1182075324; called by muse, mutect2, varscan2
- CDK16 | c.-102G>A | 5'UTR (SNP) | VAF 13/103 reads (13%) | catalogued as rs1556796361; called by muse, mutect2, varscan2
- COL9A2 | c.363+24G>A | Intron (SNP) | VAF 26/416 reads (6%) | called by muse, mutect2
- CPLANE1 | chr5:37247668 T>C | 5'Flank (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- DCAF17 | c.-38C>G | 5'UTR (SNP) | VAF 33/263 reads (13%) | called by muse, mutect2, varscan2
- DDR1 | c.2601+56T>C | Intron (SNP) | VAF 38/205 reads (19%) | called by muse, mutect2, varscan2
- DNM2 | c.1336-16C>G | Intron (SNP) | VAF 34/313 reads (11%) | catalogued as COSV58969699; called by muse, mutect2, varscan2
- EIF5AL1 | chr10:79507617 G>A | 5'Flank (SNP) | VAF 70/595 reads (12%) | catalogued as rs374067078; called by muse, varscan2
- FBXL8 | c.*169G>C | 3'UTR (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- IMPDH1 | c.-22_-18del | 5'UTR (DEL) | VAF 135/526 reads (26%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.-322-85983G>T | Intron (SNP) | VAF 56/233 reads (24%) | called by muse, mutect2, varscan2
- MYH16 | n.3848G>A | RNA (SNP) | VAF 24/169 reads (14%) | catalogued as rs1017368789; called by muse, mutect2, varscan2
- NINJ2 | c.-73G>A | 5'UTR (SNP) | VAF 23/117 reads (20%) | catalogued as rs747357110, COSV100523117; called by muse, mutect2, varscan2
- PSMA1 | c.-29C>G | 5'UTR (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2554G>C | Intron (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- SLAMF1 | c.*488C>A | 3'UTR (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- SNX19 | chr11:130862034 C>T | 3'Flank (SNP) | VAF 25/165 reads (15%) | called by muse, mutect2, varscan2
- SSPOP | n.1452C>G | RNA (SNP) | VAF 15/328 reads (5%) | called by muse, mutect2
- STX1A | c.357+11G>A | Intron (SNP) | VAF 27/220 reads (12%) | catalogued as rs782105828; called by muse, varscan2
- STXBP5 | c.2080+1430G>A | Intron (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2
- TLE4 | c.609+17247G>A | Intron (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2
- TMEM135 | c.*3639A>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- TSPYL1 | c.-8T>C | 5'UTR (SNP) | VAF 69/390 reads (18%) | catalogued as rs768821482; called by muse, mutect2, varscan2
- TTN | c.10360+1444G>C | Intron (SNP) | VAF 8/164 reads (5%) | catalogued as COSV100622464; called by muse, mutect2
- UCHL5 | chr1:193059978 C>G | 5'Flank (SNP) | VAF 21/128 reads (16%) | catalogued as COSV100814681; called by muse, mutect2, varscan2
- ZNF268 | c.362-43C>G | Intron (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
